Gene-level copy-number profile of tumor specimen HTMCP-03-06-02442-01A from CGCI case HTMCP-03-06-02442, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 45.5 years (16,606 days).
Specimen HTMCP-03-06-02442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f9d2ad19-acd4-4eef-8290-5a0eb057381f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02442-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/46acdb51-bb84-48cb-b684-1c6e2f42e20d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,821; copy number 2: 27,801; copy number 3: 21,994; copy number 4: 3,996; copy number 5: 904; copy number 6: 406; copy number 7: 397; copy number 8: 65.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:229,606,238–229,606,299, 1 gene (within-gene range 0–1): RNU7-9P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,772 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 6–7 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,329,643, 12 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr14:22,066,016–22,505,167, 64 genes, copy number 8 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.
- chr15:19,878,555–19,988,117, 8 genes, copy number 5: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7.
- chr15:22,606,022–23,367,231, 29 genes, copy number 5: GOLGA8IP, RN7SL495P, WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P.
- chr15:28,111,040–56,918,571, 729 genes, copy number 5 (broad region; genes not listed).
- chr15:58,587,507–60,402,883, 51 genes, copy number 5 (within-gene range 4–5): AC018904.1, ADAM10, HMGB1P51, AC091046.1, HSP90AB4P, RN7SKP95, AC091046.2, AC090515.6, AC090515.3, SNORD3P1, AC090515.2, MINDY2, AC090515.5, AC090515.4, ZNF444P1, RNF111, AC090515.1, SLTM, AC025918.1, AC025918.2, AC092757.1, CCNB2, AC092757.3, AC092757.2, MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1, RNU6-212P, AC092868.2, FAM81A, NSA2P4, AC092868.1, Y_RNA, AC092754.2, AC092754.1, RNA5SP396, GCNT3, GTF2A2, AC092755.1, BNIP2, PIGHP1, AC092755.2, RPS3AP6, AC092079.1, NMNAT1P5, FOXB1, MESTP2, AC009654.1, ANXA2.
- chr15:98,954,149–99,716,466, 20 genes, copy number 5 (within-gene range 4–5): AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.4, RPL7P5, MEF2A, Y_RNA.
- chr17:48,382,371–48,382,586, 1 gene, copy number 5 (within-gene range 3–5): U3.
- chr19:28,883,430–32,978,229, 73 genes, copy number 5–6 (broad region; genes not listed).
- chr22:17,359,949–18,653,617, 48 genes, copy number 5–6: CECR2, FO681548.1, CLCP1, DNAJA1P6, AC007666.2, SLC25A18, AC007666.1, ATP6V1E1, BCL2L13, BID, MIR3198-1, LINC00528, MICAL3, AC016026.1, AC016026.2, MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18, FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:20,587,496–21,517,533, 56 genes, copy number 6 (within-gene range 4–6): CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2, Metazoa_SRP, TMEM191C, PI4KAP2.

Autosomal genes at a single copy (total copy number 1): 2,821. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
